Somatic mutation profile of tumor specimen TCGA-ZQ-A9CR-01A (aliquot TCGA-ZQ-A9CR-01A-11D-A397-08) from TCGA case TCGA-ZQ-A9CR, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.7 years (29,107 days).
Specimen TCGA-ZQ-A9CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 013474eb-64dd-4968-8b04-7dec4a3abda9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZQ-A9CR-10A (Blood Derived Normal), aliquot TCGA-ZQ-A9CR-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0fc5065-a515-433b-822b-bcae570c1876

The open-access MAF lists 118 somatic variants for this specimen: 88 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 27, Frame Shift Del 2, Splice Site 2, Splice Region 2, Frame Shift Ins 2, Nonsense Mutation 2, 5'UTR 1, In Frame Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.75-2A>G p.X25_splice | Splice Site (SNP) | VAF 28/65 reads (43%) | catalogued as rs1131691020, COSV99463573; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.3485G>A p.R1162Q | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1370054312, COSV99559949; called by muse, mutect2, varscan2
- ACAP1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs747658913, COSV99342061; called by muse, mutect2, varscan2
- ADCY1 | c.2618C>A p.S873Y | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99812993; called by muse, mutect2, varscan2
- ADGRV1 | c.13507A>C p.S4503R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs764716759, COSV67979835, COSV67980159, COSV67983377; called by muse, mutect2, varscan2
- AMPH | c.551A>C p.N184T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100343870; called by muse, mutect2, varscan2
- ANKRD50 | c.481T>A p.C161S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV101539058; called by muse, mutect2, varscan2
- ASAP1 | c.2710A>G p.R904G | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV100727975; called by muse, mutect2
- ATP11A | c.305T>A p.F102Y | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99370113; called by muse, mutect2, varscan2
- ATP1A2 | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746795369, CM137113, COSV63403531; called by muse, mutect2, varscan2
- BOD1L1 | c.6158G>T p.G2053V | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV50032230; called by muse, mutect2
- BVES | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.114); catalogued as COSV100115029, COSV100115164; called by muse, mutect2, varscan2
- CDH6 | c.2289C>A p.D763E | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV54081121; called by muse, mutect2
- CHST13 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100081405; called by muse, mutect2, varscan2
- CMYA5 | c.7410G>C p.K2470N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV101484052, COSV101484416; called by muse, mutect2, varscan2
- CNTN1 | c.1220A>C p.K407T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.173); catalogued as COSV100750888; called by muse, mutect2, varscan2
- CNTNAP5 | c.3387A>T p.E1129D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101444296; called by mutect2, varscan2
- CPOX | c.1187A>G p.N396S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99939203; called by muse, mutect2, varscan2
- CUL9 | c.2858G>T p.R953L | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV52729770, COSV99336138; called by muse, mutect2
- DGKB | c.1759T>C p.F587L | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV99343861; called by muse, mutect2, varscan2
- DHRS2 | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99160670; called by muse, mutect2, varscan2
- DICER1 | c.1874T>G p.V625G | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100602613; called by muse, mutect2
- DLG2 | c.1799G>C p.R600T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99720263; called by muse, varscan2
- DOCK10 | c.1259T>G p.I420S | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV99291918; called by muse, mutect2, varscan2
- DPPA5 | c.111C>T p.F37= | Splice Region (SNP) | VAF 11/88 reads (13%) | catalogued as COSV64875441; called by muse, mutect2, varscan2
- ETFDH | c.684+1G>T p.X228_splice | Splice Site (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100310136, COSV57015250; called by muse, mutect2, varscan2
- F3 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.408); catalogued as COSV100474447; called by muse, mutect2, varscan2
- FAM3B | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs556115707, COSV63613384; called by muse, mutect2, varscan2
- FAT3 | c.3746A>G p.D1249G | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99971650; called by muse, mutect2
- FLRT2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as rs201981148, COSV58140190; called by muse, mutect2, varscan2
- FNIP1 | c.338A>G p.Q113R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV100330630; called by muse, mutect2, varscan2
- GCN1 | c.1208T>A p.L403* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100326112; called by muse, mutect2
- GYPC | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99392111; called by muse, mutect2, varscan2
- H2BC1 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs142382084; called by muse, mutect2
- HIVEP2 | c.2264C>T p.T755M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs779085758, COSV99175837; called by muse, mutect2, varscan2
- IL17F | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs772268344, COSV100277310; called by muse, mutect2, varscan2
- ITPRID1 | c.2872C>T p.H958Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.693); catalogued as COSV100087652; called by muse, mutect2, varscan2
- KCNB2 | c.512G>A p.C171Y | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.885); catalogued as COSV101579028; called by muse, mutect2
- KHDRBS3 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100879073, COSV63415230; called by muse, mutect2, varscan2
- LAMA1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs780440007, COSV67531188; called by muse, mutect2, varscan2
- LAMA2 | c.2242A>G p.T748A | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.68); catalogued as rs765192334, COSV101370891; called by muse, mutect2, varscan2
- LELP1 | c.131T>G p.F44C | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100907361; called by muse, mutect2, varscan2
- LRP1B | c.12085C>A p.P4029T | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750582438, COSV101261707; called by muse, mutect2
- MAPRE1 | c.578C>A p.A193E | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as COSV100980415; called by muse, varscan2
- MTMR7 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV99472766; called by muse, mutect2
- MTR | c.3334A>C p.K1112Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100855588; called by muse, mutect2, varscan2
- MTUS2 | c.2194T>A p.F732I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101462387, COSV101462426; called by muse, mutect2, varscan2
- NAP1L2 | c.1115_1116insG p.N372Kfs*17 | Frame Shift Ins (INS) | VAF 32/92 reads (35%) | catalogued as COSV100999238; called by mutect2, pindel, varscan2
- NRK | c.3519A>C p.E1173D | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as COSV54607387, COSV99689315; called by muse, mutect2, varscan2
- NTRK3 | c.50T>A p.L17* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100448211; called by muse, mutect2
- NUP155 | c.3824T>C p.V1275A (on ENST00000231498 / NM_153485.3; = p.V1216A on NM_004298.4) | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV99195335; called by muse, mutect2
- OR56A3 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs777153187, COSV61568506, COSV61569191; called by muse, mutect2, varscan2
- PC | c.2270G>T p.S757I | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100547196; called by muse, mutect2, varscan2
- PHTF1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs751482380, COSV100760204; called by muse, mutect2, varscan2
- PIH1D2 | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1555184574, COSV99735640; called by muse, mutect2
- PLCH2 | c.1147A>G p.I383V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.042); catalogued as COSV99617265; called by muse, varscan2
- PLSCR1 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV100678481; called by muse, mutect2, varscan2
- PLXDC2 | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV101023308; called by muse, mutect2, varscan2
- PPP1R36 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs767950225, COSV100073073; called by muse, mutect2, varscan2
- PRKG1 | c.1362A>C p.E454D | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100907515; called by muse, mutect2
- PTPRR | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752997522, COSV51739829; called by muse, mutect2, varscan2
- RGS5 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100009418; called by muse, mutect2, varscan2
- RIMS1 | c.2582A>G p.E861G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV99330927; called by muse, mutect2, varscan2
- RIPOR2 | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.628); catalogued as COSV99430212; called by muse, mutect2, varscan2
- ROBO2 | c.2750G>T p.G917V | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100170319; called by muse, mutect2, varscan2
- RYR2 | c.8681A>C p.K2894T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100773170, COSV63703647, COSV63708528; called by muse, mutect2, varscan2
- SAR1B | c.483G>T p.G161= | Splice Region (SNP) | VAF 20/104 reads (19%) | catalogued as COSV101284206; called by muse, mutect2, varscan2
- SLC4A11 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101196141; called by muse, mutect2, varscan2
- SLC8A1 | c.655T>G p.Y219D | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100247558; called by muse, mutect2, varscan2
- SLCO5A1 | c.2204G>C p.R735P | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52657511, COSV99481162; called by muse, mutect2, varscan2
- SPTA1 | c.6802G>T p.V2268L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV100935657; called by muse, mutect2, varscan2
- SYNE1 | c.4668G>C p.K1556N (on ENST00000367255 / NM_182961.4; = p.K1563N on NM_033071.3) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs774194598, COSV99581310; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAS2R43 | c.614A>T p.H205L | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101115718; called by muse, varscan2
- TLR3 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs141634515; called by muse, mutect2, varscan2
- TMEM101 | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV99244004; called by muse, mutect2, varscan2
- TMEM132E | c.2405A>G p.Y802C (on ENST00000321639; = p.Y892C on NM_001304438.2) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100396487; called by muse, mutect2, varscan2
- TRPC4 | c.2029T>G p.L677V | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100156719, COSV59010317; called by muse, mutect2, varscan2
- TTN | c.20456C>T p.P6819L (on ENST00000591111; = p.P5892L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | PolyPhen possibly damaging (0.747); catalogued as rs775519360, COSV100632822; called by muse, mutect2, varscan2
- TUSC3 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65879134, COSV65887519; called by muse, mutect2, varscan2
- UFM1 | c.137C>A p.T46K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99522694; called by muse, mutect2
- ZFP90 | c.1879C>G p.H627D | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101238837; called by muse, mutect2
- ZSWIM2 | c.69A>T p.Q23H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99720598; called by muse, mutect2, varscan2
- CFAP57 | c.1633_1636del p.K545Efs*40 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.1834_1845del p.A612_D615del | In Frame Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- FRG2C | c.282A>T p.E94D | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCLO | c.5647del p.V1883Ffs*29 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- SNX14 | c.641dup p.N214Kfs*27 (on ENST00000314673 / NM_001350535.1; = p.N170Kfs*27 on NM_020468.5 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 10/81 reads (12%) | called by mutect2, pindel, varscan2
- TRGC1 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.331); called by muse, mutect2
- ATP4A | c.168G>A p.Q56= | Silent (SNP) | VAF 19/216 reads (9%) | catalogued as COSV99383149; called by muse, mutect2
- C12orf29 | c.921T>C p.F307= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100470025; called by muse, mutect2, varscan2
- CCDC85A | c.540C>T p.C180= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs766590594, COSV101339372; called by muse, mutect2, varscan2
- CTTNBP2 | c.3168G>A p.T1056= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs140231051; called by muse, mutect2, varscan2
- HGS | c.177C>T p.H59= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1322944543, COSV61266937; called by muse, mutect2, varscan2
- KCND2 | c.15G>A p.V5= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as COSV100478963; called by muse, mutect2, varscan2
- KCNG1 | c.468C>T p.I156= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs147442458; called by muse, mutect2, varscan2
- KRT6A | c.534C>T p.I178= | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as rs773542280, COSV58103866; called by muse, mutect2, varscan2
- LRP1 | c.10086C>T p.H3362= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99677508; called by mutect2, varscan2
- MYH13 | c.1683A>G p.K561= | Silent (SNP) | VAF 8/125 reads (6%) | catalogued as COSV52831810; called by muse, mutect2
- NEDD4 | c.801C>A p.V267= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV100164177; called by muse, mutect2, varscan2
- OR13A1 | c.423C>T p.Y141= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1324546991, COSV100980963; called by muse, mutect2, varscan2
- OR6K3 | c.513C>T p.I171= (on ENST00000368146; = p.I155= on NM_001005327.2) | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV63745957; called by muse, mutect2, varscan2
- OXSM | c.780C>T p.P260= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV99772149; called by muse, mutect2, varscan2
- PANK1 | c.1113G>A p.L371= (on ENST00000307534 / NM_148977.2; = p.L146= on NM_138316.4) | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100285863; called by muse, mutect2, varscan2
- PRR19 | c.1035G>A p.P345= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs373478238; called by muse, mutect2, varscan2
- PWP1 | c.774T>A p.A258= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV101338862; called by muse, mutect2, varscan2
- RASGRF2 | c.2526G>A p.A842= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs755800361, COSV54127393; called by muse, mutect2, varscan2
- RPE | c.9G>A p.S3= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs1027231806, COSV99781188; called by muse, mutect2, varscan2
- SLC9B1 | c.534G>A p.R178= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV99600296; called by muse, mutect2, varscan2
- TAF1L | c.3645C>T p.R1215= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as COSV99645541; called by muse, mutect2, varscan2
- TBX18 | c.444C>G p.L148= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as rs1562268280, COSV100858599; called by muse, mutect2
- TEKT5 | c.300G>T p.L100= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as rs952349048, COSV99296459; called by muse, mutect2
- TREM2 | c.54C>A p.A18= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100632719; called by muse, mutect2
- TTN | c.87627C>T p.G29209= (on ENST00000591111; = p.G21785= on NM_003319.4) | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100632820; called by muse, mutect2, varscan2
- ZFHX4 | c.4023G>T p.V1341= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99268428; called by muse, mutect2
- ZNF800 | c.1767T>C p.H589= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV99758244; called by muse, mutect2
- KPRP | c.-1C>T | 5'UTR (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100908823; called by muse, mutect2, varscan2
- PDE4D | c.456-140799A>C | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100509269; called by muse, mutect2, varscan2
- SNORD116-4 | n.72G>A | RNA (SNP) | VAF 38/296 reads (13%) | catalogued as rs760400980; called by muse, mutect2, varscan2
